Somatic mutation profile of tumor specimen 0DCWBF from CCDI case PBBMIX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.6 years (583 days).
Specimen 0DCWBF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 854ed2b6-a3d7-41b1-935d-e67aeac79563.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCWB4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cf476549-3cf4-418e-8358-529ae368561d

The open-access MAF lists 5 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 2, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCOLCE2 | c.58C>A p.L20I | Missense Mutation (SNP) | VAF 157/324 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- ZNF148 | c.1931C>G p.S644C | Missense Mutation (SNP) | VAF 350/930 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.237); called by muse, varscan2
- PMEL | c.1332C>A p.I444= | Silent (SNP) | VAF 86/852 reads (10%) | called by muse, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 8/84 reads (10%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 8/83 reads (10%) | called by muse, varscan2
